Somatic mutation profile of tumor specimen TCGA-AD-A5EJ-01A (aliquot TCGA-AD-A5EJ-01A-11D-A28G-10) from TCGA case TCGA-AD-A5EJ, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIA; Age at diagnosis: 74.4 years (27,180 days).
Specimen TCGA-AD-A5EJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b4e40c8-fdd0-4bbc-9507-d409bd8a0cd0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AD-A5EJ-10A (Blood Derived Normal), aliquot TCGA-AD-A5EJ-10A-01D-A28G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ecdc098-89b2-4fba-97a8-ca507eae01ef

The open-access MAF lists 1,930 somatic variants for this specimen: 1,401 protein-altering or splice-affecting, 375 silent, 154 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 881, Silent 375, Frame Shift Del 337, Frame Shift Ins 82, 3'UTR 61, Intron 53, Nonsense Mutation 43, Splice Site 22, Splice Region 21, 5'UTR 18, In Frame Del 11, RNA 9.

Variants (750 of 1,930; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGL | c.3911del p.N1304Ifs*10 | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | catalogued as rs745757264; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AGXT | c.33dup p.K12Qfs*156 | Frame Shift Ins (INS) | VAF 30/102 reads (29%) | catalogued as rs180177201; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- B4GALNT1 | c.263del p.G88Afs*24 | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | catalogued as rs745744124; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CHD8 | c.4611del p.V1538* (on ENST00000646647 / NM_001170629.2; = p.V1259* on NM_020920.4) | Frame Shift Del (DEL) | VAF 21/68 reads (31%) | catalogued as rs1555314317; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ENAM | c.588+1dup | Frame Shift Ins (INS) | VAF 14/54 reads (26%) | catalogued as rs752102959; ClinVar: pathogenic; called by mutect2, varscan2
- KPTN | c.1225C>T p.R409* | Nonsense Mutation (SNP) | VAF 28/78 reads (36%) | catalogued as rs761616995, COSV52637863; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- LTBP2 | c.5446dup p.H1816Pfs*28 | Frame Shift Ins (INS) | VAF 24/85 reads (28%) | catalogued as rs777661862, COSV56208604; ClinVar: pathogenic; called by mutect2, varscan2
- MLH1 | c.588del p.K196Nfs*6 | Frame Shift Del (DEL) | VAF 13/56 reads (23%) | catalogued as rs63751653, CM151408, COSV51624461; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 22/64 reads (34%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- MYH7 | c.3133C>T p.R1045C | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs45611033, CM086874, COSV62516082; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 36/88 reads (41%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- NR2E3 | c.931C>T p.R311W | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.293); catalogued as rs767442358, COSV100489572; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- OFD1 | c.710del p.K237Sfs*6 | Frame Shift Del (DEL) | VAF 16/74 reads (22%) | catalogued as rs312262845; ClinVar: pathogenic; called by mutect2, varscan2
- PARK7 | c.189dup p.E64Rfs*5 | Frame Shift Ins (INS) | VAF 13/99 reads (13%) | catalogued as rs759703272; ClinVar: likely pathogenic; called by mutect2, varscan2
- PIK3CA | c.1625A>G p.E542G | Missense Mutation (SNP) | VAF 52/150 reads (35%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.221); catalogued as rs1057519927, COSV55876800, COSV55881194, COSV55893680; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 27/84 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.1048dup p.T350Nfs*11 | Frame Shift Ins (INS) | VAF 63/216 reads (29%) | catalogued as rs797045066; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RUNX2 | c.90del p.S31Pfs*9 | Frame Shift Del (DEL) | VAF 29/106 reads (27%) | catalogued as rs397515538; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- STXBP1 | c.1651C>T p.R551C | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs796053373, CM125342, CM1513639, COSV64813774; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TOP3A | c.2271del p.R758Gfs*15 | Frame Shift Del (DEL) | VAF 25/76 reads (33%) | catalogued as rs752838075; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.572_574del p.P191del | In Frame Del (DEL) | VAF 20/154 reads (13%) | hotspot (GDC flag); catalogued as rs1555525902; called by pindel, varscan2
- TRPS1 | c.1591C>T p.R531* (on ENST00000220888 / NM_001330599.2; = p.R544* on NM_014112.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 20/70 reads (29%) | catalogued as rs886040971, CM010480, COSV55235791; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TSC1 | c.1388del p.L463* | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | catalogued as rs1064796237; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- WDR72 | c.2686C>T p.R896* | Nonsense Mutation (SNP) | VAF 31/92 reads (34%) | catalogued as rs557128345, CM109077, COSV64751129; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.4186G>A p.V1396M | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59386217; called by muse, mutect2, varscan2
- AADAC | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV51760028; called by muse, mutect2, varscan2
- AADACL3 | c.762del p.Q255Kfs*14 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | catalogued as rs746497630; called by mutect2, varscan2
- AASDH | c.1319del p.L440Wfs*43 | Frame Shift Del (DEL) | VAF 26/70 reads (37%) | catalogued as rs770970036; called by mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 73/109 reads (67%) | catalogued as rs749943218; called by mutect2, varscan2
- ABCC9 | c.2950C>T p.R984C | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs78979794; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCD4 | c.454C>T p.R152* | Nonsense Mutation (SNP) | VAF 8/84 reads (10%) | catalogued as rs1282760239, COSV100084523; called by muse, mutect2
- ABCG2 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.295); catalogued as rs750852563; called by muse, mutect2, varscan2
- ABI3BP | c.1385C>T p.T462I | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as rs780386031; called by muse, mutect2, varscan2
- ABL1 | c.1739C>T p.P580L | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs774635743, COSV59339187; called by muse, mutect2, varscan2
- ABO | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs866584466, COSV101506000, COSV71743440; called by muse, mutect2
- ABR | c.2526del p.I843Ffs*41 (on ENST00000302538 / NM_021962.5; = p.I806Ffs*41 on NM_001092.5) | Frame Shift Del (DEL) | VAF 27/68 reads (40%) | catalogued as rs750897785; called by mutect2, pindel, varscan2
- AC004076.1 | c.263G>A p.S88N | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated (0.08); catalogued as rs1323637749; called by muse, mutect2, varscan2
- AC004922.1 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.818); catalogued as rs1349181083, COSV53555502; called by mutect2, varscan2
- AC008397.2 | c.1438C>A p.L480I | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV53208607; called by muse, mutect2, varscan2
- ACAD8 | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as rs372521286; called by muse, mutect2, varscan2
- ACIN1 | c.1340dup p.V448Cfs*9 | Frame Shift Ins (INS) | VAF 35/100 reads (35%) | catalogued as rs748065675; called by mutect2, varscan2
- ACKR2 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as rs781335034; called by muse, varscan2
- ACSM3 | c.1645dup p.T549Nfs*29 | Frame Shift Ins (INS) | VAF 12/32 reads (38%) | catalogued as rs757021642; called by mutect2, varscan2
- ACSM5 | c.1322A>C p.K441T | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100089468, COSV59370639; called by muse, mutect2
- ACSS3 | c.902G>A p.G301D | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1239532528, COSV54096233, COSV54104713; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 37/59 reads (63%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAL | c.651dup p.E218Rfs*11 | Frame Shift Ins (INS) | VAF 18/65 reads (28%) | catalogued as rs778831705; called by mutect2, varscan2
- ADAM12 | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV64109086; called by muse, mutect2, varscan2
- ADAMTS1 | c.1116G>T p.M372I | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.552); catalogued as COSV99536465; called by muse, mutect2
- ADAMTS10 | c.2293del p.Q765Sfs*7 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | catalogued as rs782743337; called by mutect2, varscan2
- ADAMTS18 | c.2085del p.F695Lfs*7 | Frame Shift Del (DEL) | VAF 38/121 reads (31%) | catalogued as rs772504358, COSV51414270; called by mutect2, varscan2
- ADAMTS4 | c.1750G>A p.E584K | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs746213424, COSV63490498, COSV63491023; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1195C>T p.R399W | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368995584; called by muse, mutect2, varscan2
- ADARB2 | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs538700330, COSV67219587; called by muse, mutect2
- ADCY8 | c.671T>C p.V224A | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.935); catalogued as rs1402238883; called by muse, mutect2, varscan2
- ADGRL2 | c.2928T>G p.Y976* (on ENST00000370717 / NM_001366005.1; = p.Y963* on NM_012302.4) | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as COSV54673907; called by muse, mutect2, varscan2
- AFDN | c.2914C>T p.R972C | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs778409493, COSV60047772; called by muse, mutect2, varscan2
- AFDN | c.4273C>T p.R1425C | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs754436231, COSV60047781; called by muse, mutect2, varscan2
- AFF2 | c.470C>A p.P157H | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.807); catalogued as COSV100651299; called by muse, mutect2, varscan2
- AFF2 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 92/282 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.965); catalogued as COSV53994875; called by muse, mutect2
- AGL | c.3169C>T p.P1057S | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV54057890; called by muse, mutect2, varscan2
- AIFM3 | c.1120del p.E374Sfs*8 | Frame Shift Del (DEL) | VAF 24/105 reads (23%) | catalogued as rs1569149441; called by mutect2, pindel, varscan2
- ALAS2 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as HM040080, COSV100238213, COSV58194193; called by muse, mutect2, varscan2
- ALDH5A1 | c.1108G>A p.V370I | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs754091433, COSV62373108; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMOTL2 | c.599del p.P200Lfs*19 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs756346527; called by mutect2, varscan2
- AMPD2 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 11/193 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as rs1405573662, COSV99858069; called by muse, mutect2
- ANGPT2 | c.700del p.I234* | Frame Shift Del (DEL) | VAF 24/102 reads (24%) | catalogued as rs34047276; called by mutect2, varscan2
- ANK3 | c.1970C>T p.A657V | Missense Mutation (SNP) | VAF 66/182 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as COSV55048039; called by muse, mutect2, varscan2
- ANKK1 | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs139195339; called by muse, mutect2, varscan2
- ANKRD11 | c.7735C>T p.R2579C | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1567537413, COSV56358396; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD27 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs772176447, COSV100043261; called by muse, varscan2
- ANKRD34B | c.1247del p.P416Qfs*4 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | catalogued as rs779065930, COSV100103683; called by mutect2, pindel, varscan2
- ANKUB1 | c.752G>A p.G251D | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757464210, COSV67167815; called by muse, mutect2, varscan2
- ANOS1 | c.1396G>A p.A466T | Missense Mutation (SNP) | VAF 177/457 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.021); catalogued as COSV52923792, COSV99391344; called by muse, mutect2, varscan2
- ANXA6 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 32/128 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); catalogued as rs1370054666, COSV62907250; called by muse, mutect2, varscan2
- AQP1 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as rs183830991; called by muse, mutect2, varscan2
- AQP8 | c.363del p.M122Cfs*10 | Frame Shift Del (DEL) | VAF 8/63 reads (13%) | catalogued as rs759782104; called by mutect2, pindel, varscan2
- AR | c.271_273dup p.Q91dup | In Frame Ins (INS) | VAF 28/106 reads (26%) | catalogued as rs753526329; called by mutect2, varscan2
- ARAP3 | c.4004G>A p.R1335H | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750355617, COSV53353818; called by muse, mutect2, varscan2
- ARFGEF3 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as rs761083705; called by muse, mutect2, varscan2
- ARHGAP39 | c.11C>T p.T4M | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.108); catalogued as rs150289481; called by muse, mutect2, varscan2
- ARHGAP5 | c.704T>C p.I235T | Missense Mutation (SNP) | VAF 61/286 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs763517057; called by muse, mutect2, varscan2
- ARMC4 | c.2257C>T p.R753W | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs763662864, COSV100537114, COSV59456453; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.50del p.K17Rfs*21 | Frame Shift Del (DEL) | VAF 93/317 reads (29%) | catalogued as rs1290336606; called by mutect2, pindel, varscan2
- ARNT2 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57587961; called by muse, mutect2, varscan2
- ARRB1 | c.466_468del p.E156del | In Frame Del (DEL) | VAF 16/64 reads (25%) | catalogued as rs759500119; called by pindel, varscan2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | catalogued as rs753865255; called by mutect2, varscan2
- ARV1 | c.518del p.K173Sfs*8 | Frame Shift Del (DEL) | VAF 18/49 reads (37%) | catalogued as rs544784472, COSV59618356; called by mutect2, varscan2
- ASCC3 | c.489del p.F163Lfs*5 | Frame Shift Del (DEL) | VAF 9/63 reads (14%) | catalogued as rs747570359; called by mutect2, varscan2
- ATF7IP | c.3752G>A p.R1251H | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1400118792, COSV53766932, COSV53779220; called by muse, mutect2, varscan2
- ATG2A | c.3874C>T p.R1292C | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs757810630, COSV104426002; called by muse, mutect2, varscan2
- ATP2B2 | c.2241G>T p.E747D (on ENST00000352432; = p.E713D on NM_001683.5) | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV100660402; called by muse, mutect2
- ATP6V1E2 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.466); catalogued as rs549725173; called by muse, mutect2, varscan2
- ATPAF1 | c.568C>T p.R190W (on ENST00000574428; = p.R213W on NM_022745.4) | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs925255113, COSV61305250, COSV61305468; called by muse, mutect2, varscan2
- ATXN2L | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57365138; called by muse, mutect2, varscan2
- B3GALT4 | c.725del p.G242Afs*48 | Frame Shift Del (DEL) | VAF 21/76 reads (28%) | catalogued as rs779828300; called by mutect2, pindel, varscan2
- B3GNT3 | c.547_549del p.F183del | In Frame Del (DEL) | VAF 41/126 reads (33%) | catalogued as rs752969910; called by pindel, varscan2
- B4GALT3 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 55/193 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs367870203, COSV60527194; called by muse, mutect2, varscan2
- BAHCC1 | c.1357C>T p.R453W | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs574818751, COSV57022756; called by muse, mutect2
- BCORL1 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.387); catalogued as rs368979206, COSV54398403; called by muse, mutect2, varscan2
- BCORL1 | c.1888C>T p.R630C | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1167221282, COSV54408411; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 12/79 reads (15%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BDP1 | c.938del p.L313* | Frame Shift Del (DEL) | VAF 42/135 reads (31%) | catalogued as rs752427670; called by mutect2, varscan2
- BEND6 | c.827A>G p.Q276R | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.037); catalogued as rs1309642285; called by muse, mutect2, varscan2
- BIN3 | c.77G>T p.R26M | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV52385208; called by muse, mutect2, varscan2
- BMP2K | c.3164G>A p.R1055K | Missense Mutation (SNP) | VAF 60/197 reads (30%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.031); catalogued as COSV55008554; called by muse, mutect2, varscan2
- BMP8B | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 100/302 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); catalogued as rs761175006, COSV59594414, COSV59594681; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 33/88 reads (38%) | catalogued as rs772920507, COSV65808737; called by mutect2, varscan2
- BNC2 | c.2210C>T p.S737F | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as COSV101034076; called by muse, mutect2, varscan2
- BORCS7 | c.103C>T p.L35F | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.315); catalogued as COSV54917545; called by muse, mutect2, varscan2
- BPIFC | c.30G>T p.W10C | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV55912858; called by muse, mutect2, varscan2
- BRCA2 | c.9945dup p.E3316Rfs*11 | Frame Shift Ins (INS) | VAF 11/46 reads (24%) | catalogued as rs431825381; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- BRD1 | c.2666G>A p.R889H (on ENST00000216267 / NM_001349940.1; = p.R1020H on NM_001304808.3) | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.613); catalogued as rs757367533, COSV53454810; called by muse, mutect2, varscan2
- BRD1 | c.2074C>T p.R692W | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.46); catalogued as rs1299198029, COSV53458816; called by muse, mutect2
- BRWD3 | c.3418del p.A1140Lfs*42 | Frame Shift Del (DEL) | VAF 11/94 reads (12%) | catalogued as COSV100956344; called by mutect2, pindel, varscan2
- BTLA | c.742C>A p.L248M | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV57938958; called by muse, mutect2, varscan2
- C12orf4 | c.707del p.N236Tfs*22 | Frame Shift Del (DEL) | VAF 30/89 reads (34%) | catalogued as COSV54210606; called by mutect2, pindel, varscan2
- C16orf46 | c.116dup p.N39Kfs*11 | Frame Shift Ins (INS) | VAF 17/54 reads (31%) | catalogued as rs753533248; called by mutect2, varscan2
- C1QA | c.388G>A p.V130M | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.104); catalogued as rs568891417; called by muse, mutect2, varscan2
- C1QTNF3 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51469132; called by muse, mutect2, varscan2
- C1S | c.842del p.K281Rfs*39 | Frame Shift Del (DEL) | VAF 23/149 reads (15%) | catalogued as rs781818365; called by mutect2, pindel, varscan2
- C2orf74 | c.107del p.L36Yfs*25 | Frame Shift Del (DEL) | VAF 17/66 reads (26%) | catalogued as rs1265298443; called by mutect2, pindel, varscan2
- C5orf22 | c.965C>T p.T322M | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as rs760715623, COSV57598995; called by muse, mutect2, varscan2
- C6 | c.1817G>A p.R606Q | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.019); catalogued as rs760471024, COSV54715634; called by muse, varscan2
- C6 | c.1783dup p.Q595Pfs*8 | Frame Shift Ins (INS) | VAF 11/106 reads (10%) | catalogued as rs767886734; called by pindel, varscan2
- C7 | c.2436G>T p.E812D | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as COSV57476003, COSV57480560; called by muse, mutect2, varscan2
- CA12 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs1420074847, COSV99457879, COSV99458406; called by muse, mutect2, varscan2
- CA13 | c.188G>A p.S63N | Missense Mutation (SNP) | VAF 101/295 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58798282; called by muse, mutect2, varscan2
- CACNA1C | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 31/281 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1238581042; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1C | c.5647del p.Q1883Sfs*28 | Frame Shift Del (DEL) | VAF 21/79 reads (27%) | catalogued as rs1412974929; called by mutect2, pindel, varscan2
- CACNA2D4 | c.541G>A p.V181M | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV54952802; called by muse, mutect2, varscan2
- CAMK1 | c.486C>A p.D162E | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV56538058; called by muse, mutect2, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 19/73 reads (26%) | catalogued as rs1375954479; called by mutect2, pindel, varscan2
- CAMTA2 | c.2597del p.P866Lfs*9 | Frame Shift Del (DEL) | VAF 22/76 reads (29%) | catalogued as rs745547658; called by mutect2, varscan2
- CASC3 | c.1603G>A p.A535T | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.075); catalogued as rs771037006, COSV52868285; called by muse, mutect2, varscan2
- CASP5 | c.533del p.N178Ifs*8 | Frame Shift Del (DEL) | VAF 18/40 reads (45%) | catalogued as rs765105588; called by mutect2, varscan2
- CC2D1B | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as COSV52559104, COSV52563126; called by muse, mutect2, varscan2
- CCDC103 | c.327G>A p.W109* | Nonsense Mutation (SNP) | VAF 8/109 reads (7%) | catalogued as COSV53651549; called by muse, mutect2
- CCDC168 | c.21051del p.F7017Lfs*25 | Frame Shift Del (DEL) | VAF 22/68 reads (32%) | catalogued as rs397851855; called by mutect2, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 18/34 reads (53%) | catalogued as rs535192849; called by mutect2, varscan2
- CCDC18 | c.774del p.V259Wfs*15 | Frame Shift Del (DEL) | VAF 68/159 reads (43%) | catalogued as rs746565576, COSV58142470; called by mutect2, varscan2
- CCDC188 | c.194del p.G65Afs*82 | Frame Shift Del (DEL) | VAF 19/130 reads (15%) | catalogued as rs1263715661; called by mutect2, pindel, varscan2
- CCDC24 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs1347551847; called by muse, mutect2, varscan2
- CCDC92 | c.962T>C p.V321A | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); catalogued as COSV53021640; called by muse, mutect2, varscan2
- CCP110 | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 71/208 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs146335974, COSV66817211; called by muse, mutect2, varscan2
- CCP110 | c.1990G>A p.A664T | Missense Mutation (SNP) | VAF 48/493 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.752); catalogued as rs746844150, COSV66817352; called by muse, mutect2
- CCT6A | c.1240G>A p.V414M | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs1274461513; called by muse, mutect2, varscan2
- CD4 | c.498del p.K167Rfs*31 | Frame Shift Del (DEL) | VAF 66/237 reads (28%) | catalogued as rs781937995, COSV99163893; called by mutect2, pindel, varscan2
- CDC25C | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372984578; called by mutect2, varscan2
- CDC42BPB | c.3019G>A p.A1007T | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs962655009; called by muse, mutect2, varscan2
- CDH10 | c.322del p.T108Qfs*30 | Frame Shift Del (DEL) | VAF 31/91 reads (34%) | catalogued as rs748395403; called by mutect2, pindel, varscan2
- CDH4 | c.399G>A p.P133= | Splice Region (SNP) | VAF 18/62 reads (29%) | catalogued as rs1275235214, COSV64648957; called by mutect2, varscan2
- CDH9 | c.1990G>A p.G664S | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50265700; called by muse, mutect2, varscan2
- CDHR2 | c.3859C>T p.R1287W | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs373675182; called by muse, mutect2, varscan2
- CDK20 | c.564-1G>T p.X188_splice (on ENST00000325303 / NM_001039803.3; = p.X167_splice on NM_012119.4) | Splice Site (SNP) | VAF 10/69 reads (14%) | catalogued as COSV100308206; called by muse, mutect2, varscan2
- CDNF | c.466dup p.E156Gfs*11 | Frame Shift Ins (INS) | VAF 25/75 reads (33%) | catalogued as rs1183960049; called by mutect2, pindel, varscan2
- CDR1 | c.779G>T p.W260L | Missense Mutation (SNP) | VAF 52/252 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.063); catalogued as COSV100983422, COSV65164429; called by muse, mutect2, varscan2
- CDS2 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.786); catalogued as rs576280057, COSV66897950; called by muse, mutect2, varscan2
- CDS2 | c.1220G>T p.S407I | Missense Mutation (SNP) | VAF 95/269 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as COSV66898006; called by muse, mutect2, varscan2
- CELSR2 | c.6556C>T p.R2186C | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs780711008, COSV54767586; called by muse, mutect2, varscan2
- CEP350 | c.3128G>A p.G1043E | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.402); catalogued as rs779634183, COSV62604829; called by muse, mutect2, varscan2
- CEP350 | c.5700G>T p.W1900C | Missense Mutation (SNP) | VAF 81/242 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62604843; called by muse, mutect2, varscan2
- CFAP46 | c.2046del p.E683Kfs*3 | Frame Shift Del (DEL) | VAF 33/97 reads (34%) | catalogued as rs1339296916; called by mutect2, varscan2
- CHD8 | c.1478G>A p.R493Q (on ENST00000646647 / NM_001170629.2; = p.R214Q on NM_020920.4) | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as rs755646683, COSV67871608; called by muse, mutect2, varscan2
- CHIA | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as rs373325850; called by muse, mutect2, varscan2
- CHRM2 | c.1222C>A p.L408I | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV99062911; called by muse, mutect2, varscan2
- CIITA | c.2933G>A p.R978Q | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs546498273, COSV60857320; called by muse, mutect2, varscan2
- CKM | c.887A>G p.H296R | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs565428059; called by muse, mutect2, varscan2
- CLASRP | c.284dup p.L96Sfs*17 | Frame Shift Ins (INS) | VAF 18/52 reads (35%) | catalogued as rs758390677; called by mutect2, varscan2
- CLCN7 | c.917-1G>T p.X306_splice | Splice Site (SNP) | VAF 19/49 reads (39%) | catalogued as COSV99247598; called by muse, mutect2, varscan2
- CLDN18 | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT tolerated (0.77); PolyPhen benign (0.01); catalogued as rs1443429734, COSV51736920; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 33/90 reads (37%) | catalogued as rs369752219; called by mutect2, varscan2
- CNKSR1 | c.1535del p.P512Hfs*58 (on ENST00000374253 / NM_001297647.2; = p.P505Hfs*58 on NM_006314.3) | Frame Shift Del (DEL) | VAF 24/73 reads (33%) | catalogued as rs753922055; called by mutect2, pindel, varscan2
- CNOT1 | c.2706del p.Q904Sfs*9 | Frame Shift Del (DEL) | VAF 25/84 reads (30%) | catalogued as rs1397135931, COSV55313852; called by mutect2, varscan2
- CNTNAP5 | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.146); catalogued as rs765295281, COSV70502693; called by muse, mutect2, varscan2
- COL4A2 | c.1187G>A p.G396E | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64629869; called by muse, mutect2, varscan2
- COL4A4 | c.372+2T>C p.X124_splice | Splice Site (SNP) | VAF 45/138 reads (33%) | catalogued as COSV100307572; called by muse, mutect2, varscan2
- COL7A1 | c.3086C>T p.T1029M | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as rs376090628; called by muse, mutect2, varscan2
- COL7A1 | c.1166C>T p.T389M | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.412); catalogued as rs371145958; called by muse, mutect2, varscan2
- COP1 | c.2104G>T p.A702S | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); catalogued as COSV58165427; called by muse, mutect2
- COPRS | c.209del p.G70Vfs*22 | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | catalogued as COSV56632361; called by mutect2, pindel, varscan2
- COPS5 | c.921-5del | Splice Region (DEL) | VAF 28/64 reads (44%) | catalogued as rs200155628; called by mutect2, varscan2
- COQ9 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs201097286; called by muse, mutect2, varscan2
- CPNE8 | c.1646C>T p.A549V | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.131); catalogued as rs767662196, COSV100504641, COSV58837623; called by muse, mutect2, varscan2
- CR1L | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 79/203 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs1305199861, COSV54327789; called by muse, mutect2, varscan2
- CR2 | c.1224G>A p.K408= | Splice Region (SNP) | VAF 25/69 reads (36%) | catalogued as COSV104424413; called by muse, mutect2, varscan2
- CRAMP1 | c.1741G>A p.D581N | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as rs1257234848; called by muse, mutect2
- CSK | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 39/226 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs200009296, COSV54974879; called by muse, mutect2, varscan2
- CSMD1 | c.7531G>A p.E2511K (on ENST00000520002; = p.E2510K on NM_033225.6) | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs532940488, COSV59285142; called by muse, mutect2, varscan2
- CSMD2 | c.2075C>T p.P692L | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV53921902; called by muse, mutect2, varscan2
- CSMD2 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1166040845; called by muse, mutect2
- CTAGE9 | c.176del p.L59Cfs*27 | Frame Shift Del (DEL) | VAF 55/197 reads (28%) | catalogued as rs752217831; called by mutect2, pindel, varscan2
- CUL1 | c.1807-1G>T p.X603_splice | Splice Site (SNP) | VAF 24/52 reads (46%) | catalogued as COSV100296898; called by muse, mutect2, varscan2
- CXorf66 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 54/198 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.441); catalogued as rs769444048; called by muse, mutect2, varscan2
- CYP2A6 | c.418del p.V140Wfs*35 | Frame Shift Del (DEL) | VAF 45/178 reads (25%) | catalogued as COSV99991677; called by mutect2, pindel, varscan2
- CYP4F2 | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 78/213 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.19); catalogued as rs751528640, COSV50001661; called by muse, mutect2, varscan2
- DAB2IP | c.3073del p.H1025Tfs*5 (on ENST00000408936; = p.H997Tfs*5 on NM_032552.3) | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | catalogued as rs751187768; called by mutect2, varscan2
- DACT2 | c.1585del p.Q529Sfs*228 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs1298397605; called by mutect2, varscan2
- DCAF4L2 | c.1013C>T p.T338M | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV60477323; called by muse, mutect2, varscan2
- DCAF8L2 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 32/279 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as COSV101446127; called by muse, mutect2, varscan2
- DCBLD1 | c.2063C>T p.T688M | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1035734006; called by muse, mutect2, varscan2
- DCHS2 | c.1441C>A p.L481I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.073); catalogued as COSV59730134; called by muse, mutect2
- DCTN1 | c.1561C>T p.R521C | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs756634587, COSV62620576; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DDR1 | c.111G>A p.M37I | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV61322124; called by muse, mutect2, varscan2
- DEPDC5 | c.1157G>A p.S386N | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1266886686; called by muse, mutect2, varscan2
- DEUP1 | c.214C>T p.R72* | Nonsense Mutation (SNP) | VAF 50/174 reads (29%) | catalogued as rs368065712, COSV53210840; called by muse, mutect2, varscan2
- DGCR8 | c.329del p.P110Lfs*9 | Frame Shift Del (DEL) | VAF 15/81 reads (19%) | catalogued as COSV61229013; called by mutect2, pindel, varscan2
- DHX15 | c.2023C>T p.R675C | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV61026804; called by muse, mutect2, varscan2
- DHX30 | c.1945G>A p.A649T (on ENST00000445061 / NM_138615.3; = p.A610T on NM_014966.3) | Missense Mutation (SNP) | VAF 38/223 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs753357583, COSV53136322; called by muse, mutect2, varscan2
- DHX34 | c.2600-1G>T p.X867_splice | Splice Site (SNP) | VAF 18/60 reads (30%) | catalogued as COSV60896027; called by muse, mutect2, varscan2
- DHX9 | c.2588G>A p.R863H | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as rs982568068, COSV62360359; called by muse, varscan2
- DISP1 | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.984); catalogued as rs148231227, COSV52658154; called by muse, mutect2, varscan2
- DMXL1 | c.5103dup p.L1702Sfs*11 | Frame Shift Ins (INS) | VAF 29/103 reads (28%) | catalogued as rs776021446; called by mutect2, pindel, varscan2
- DNAH10 | c.2774G>T p.W925L (on ENST00000409039; = p.W864L on NM_207437.3) | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV101292478; called by muse, mutect2, varscan2
- DNAH11 | c.13240dup p.T4414Nfs*34 | Frame Shift Ins (INS) | VAF 29/114 reads (25%) | catalogued as rs759332741; called by mutect2, varscan2
- DNAH6 | c.3886T>C p.C1296R | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.034); catalogued as COSV99408439; called by muse, mutect2
- DNAH7 | c.3770del p.N1257Ifs*11 | Frame Shift Del (DEL) | VAF 88/237 reads (37%) | catalogued as rs34468832; called by mutect2, varscan2
- DNAH7 | c.2275del p.I759Sfs*5 | Frame Shift Del (DEL) | VAF 6/66 reads (9%) | catalogued as COSV56778434; called by pindel, varscan2
- DNAJC13 | c.2549+1G>A p.X850_splice | Splice Site (SNP) | VAF 5/23 reads (22%) | catalogued as rs1303362779, COSV53453102; called by muse, mutect2
- DNAJC13 | c.4068A>C p.K1356N | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53453113; called by muse, mutect2, varscan2
- DNAJC22 | c.224del p.P75Lfs*2 | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | catalogued as rs751047585; called by mutect2, pindel, varscan2
- DNLZ | c.510del p.S171Afs*119 | Frame Shift Del (DEL) | VAF 16/59 reads (27%) | catalogued as rs1156815535; called by mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK9 | c.2786A>C p.K929T (on ENST00000376460 / NM_001366676.2; = p.K930T on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.185); catalogued as COSV59633846; called by muse, mutect2, varscan2
- DOCK9 | c.1228A>G p.K410E (on ENST00000376460 / NM_001366676.2; = p.K411E on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV59633853; called by muse, mutect2, varscan2
- DOK1 | c.1282C>A p.P428T | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV51209118; called by muse, mutect2, varscan2
- DOK3 | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777637154; called by muse, mutect2, varscan2
- DPAGT1 | c.698dup p.T234Hfs*116 | Frame Shift Ins (INS) | VAF 46/148 reads (31%) | catalogued as rs35482889; called by mutect2, varscan2
- DSG4 | c.2171C>T p.T724M | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV57390177; called by muse, mutect2, varscan2
- DST | c.22192C>T p.R7398C (on ENST00000361203 / NM_001374722.1; = p.R5108C on NM_015548.5) | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868335418, COSV55015908; called by muse, mutect2, varscan2
- DST | c.17841G>T p.Q5947H (on ENST00000361203 / NM_001374722.1; = p.Q3644H on NM_015548.5) | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs778466743, COSV55022718; called by muse, mutect2, varscan2
- DTX2 | c.676G>A p.V226I | Missense Mutation (SNP) | VAF 52/502 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs199598165; called by muse, varscan2
- DUSP22 | c.511G>T p.A171S | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs753689902, COSV60527518; called by muse, mutect2, varscan2
- DUSP7 | c.1094A>C p.K365T | Missense Mutation (SNP) | VAF 72/189 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56589293; called by muse, mutect2, varscan2
- DYNC1I2 | c.169del p.R57Gfs*13 | Frame Shift Del (DEL) | VAF 35/217 reads (16%) | catalogued as rs772082432; called by mutect2*, varscan2
- EBF3 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1440026193, COSV62473876; called by muse, mutect2, varscan2
- EBPL | c.516del p.F172Lfs*7 | Frame Shift Del (DEL) | VAF 44/110 reads (40%) | catalogued as rs369293935; called by mutect2, varscan2
- EDNRB | c.1147del p.Y383Ifs*3 (on ENST00000377211 / NM_001201397.1; = p.Y293Ifs*3 on NM_000115.5) | Frame Shift Del (DEL) | VAF 8/65 reads (12%) | catalogued as rs769735757; ClinVar: risk factor; called by mutect2, pindel, varscan2
- EDRF1 | c.2591T>C p.V864A (on ENST00000356792 / NM_001202438.2; = p.V830A on NM_015608.2) | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV100523900; called by muse, mutect2
- EFHD1 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as rs761223584, COSV99898393; called by muse, mutect2, varscan2
- EGFL8 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs1382909455, COSV61248021; called by muse, mutect2, varscan2
- EGR2 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54346153; called by muse, mutect2, varscan2
- EP400 | c.538A>T p.I180F | Missense Mutation (SNP) | VAF 98/590 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.408); catalogued as COSV100202091; called by muse, mutect2, varscan2
- EPB41L2 | c.1988G>A p.R663H | Missense Mutation (SNP) | VAF 62/170 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.095); catalogued as rs201590756, COSV61354495; called by muse, mutect2, varscan2
- EPHA6 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67563189, COSV67575954; called by muse, mutect2, varscan2
- ERCC1 | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs374992813; called by muse, mutect2, varscan2
- ERCC2 | c.1532G>A p.R511Q | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs772572683, CM010225, COSV67264035; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 58/171 reads (34%) | catalogued as rs775950025; called by mutect2, varscan2
- ETNPPL | c.486dup p.E163Rfs*17 | Frame Shift Ins (INS) | VAF 9/35 reads (26%) | catalogued as rs1194314934; called by mutect2, pindel, varscan2
- EVC | c.1652del p.P551Rfs*7 | Frame Shift Del (DEL) | VAF 68/216 reads (31%) | catalogued as rs1312383000; called by mutect2, pindel, varscan2
- EVI5L | c.2078del p.K693Rfs*7 | Frame Shift Del (DEL) | VAF 12/57 reads (21%) | catalogued as COSV54489378; called by mutect2, pindel, varscan2
- EXD3 | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.68); PolyPhen benign (0.009); catalogued as rs577049845, COSV59808510, COSV59808802; called by muse, mutect2, varscan2
- EXOC3L1 | c.1292A>T p.E431V | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.136); catalogued as COSV52047049; called by muse, mutect2, varscan2
- EXOC6 | c.1212+1G>A p.X404_splice | Splice Site (SNP) | VAF 9/28 reads (32%) | catalogued as COSV99592410; called by muse, mutect2, varscan2
- EYS | c.1961dup p.N654Kfs*5 | Frame Shift Ins (INS) | VAF 24/89 reads (27%) | catalogued as rs749103801; called by pindel, varscan2
- FADS3 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as rs771731285, COSV53877564; called by muse, varscan2
- FAM178B | c.163G>A p.V55M | Missense Mutation (SNP) | VAF 64/157 reads (41%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.003); catalogued as rs890539276, COSV59968968; called by muse, mutect2, varscan2
- FAM184B | c.960dup p.L321Tfs*29 | Frame Shift Ins (INS) | VAF 24/72 reads (33%) | catalogued as rs1376616218; called by mutect2, varscan2
- FAM3D | c.586-4_586-3dup | Splice Region (INS) | VAF 7/47 reads (15%) | catalogued as rs1559492634; called by mutect2, varscan2
- FAM47A | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 136/379 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.083); catalogued as COSV60494861; called by muse, mutect2, varscan2
- FAM78B | c.251G>T p.S84I | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.136); catalogued as COSV57979043; called by muse, mutect2, varscan2
- FAM9A | c.477del p.K159Nfs*3 | Frame Shift Del (DEL) | VAF 35/126 reads (28%) | catalogued as rs748967872; called by mutect2, varscan2
- FANCL | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs146690827; called by muse, mutect2, varscan2
- FANCM | c.3436G>A p.D1146N | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.413); catalogued as rs142077813; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FARSB | c.1136T>C p.M379T | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV99918593; called by muse, mutect2
- FBXL5 | c.552T>A p.F184L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV58010255; called by muse, mutect2, varscan2
- FBXO44 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.956); catalogued as rs764071113; called by muse, mutect2, varscan2
- FBXW2 | c.363G>T p.K121N | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV61597334; called by muse, mutect2, varscan2
- FCGBP | c.8774G>A p.R2925Q | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.217); catalogued as rs781059374; called by mutect2, varscan2
- FER1L6 | c.3708del p.G1237Afs*10 | Frame Shift Del (DEL) | VAF 27/93 reads (29%) | catalogued as rs747094222, COSV67548414; called by mutect2, pindel, varscan2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 14/30 reads (47%) | catalogued as rs748969702; called by mutect2, varscan2
- FFAR3 | c.686C>A p.A229D | Missense Mutation (SNP) | VAF 85/578 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs758707923, COSV100588292; called by muse, mutect2, varscan2
- FGF9 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 73/223 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs1010781871, COSV66645719; called by muse, mutect2, varscan2
- FGFBP1 | c.78del p.V27* | Frame Shift Del (DEL) | VAF 33/88 reads (38%) | catalogued as rs144178676; called by mutect2, varscan2
- FKBP10 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1555616688; called by muse, mutect2, varscan2
- FKBP10 | c.1102G>A p.V368I | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT tolerated (0.95); PolyPhen benign (0.085); catalogued as rs370277647; called by muse, varscan2
- FKBP15 | c.1994del p.K665Rfs*9 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | catalogued as rs774060142; called by mutect2, varscan2
- FLNA | c.3094C>T p.R1032C | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs782546714; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- FLT1 | c.2788C>A p.L930I | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV56726597; called by muse, mutect2, varscan2
- FNDC1 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 57/170 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.571); catalogued as rs764191268; called by muse, mutect2, varscan2
- FRMPD3 | c.1775G>T p.R592L | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.406); catalogued as COSV52192821; called by muse, mutect2, varscan2
- G2E3 | c.1081del p.T361Lfs*16 | Frame Shift Del (DEL) | VAF 21/57 reads (37%) | catalogued as rs751355614, COSV52840527; called by mutect2, varscan2
- GADL1 | c.1097A>C p.Q366P | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs146398609; called by muse, varscan2
- GATAD2B | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs764367916, COSV100897770; called by muse, mutect2, varscan2
- GBP3 | c.1753del p.T585Pfs*9 | Frame Shift Del (DEL) | VAF 22/44 reads (50%) | catalogued as rs548474277; called by mutect2, varscan2
- GBP7 | c.500G>T p.S167I | Missense Mutation (SNP) | VAF 5/123 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV99643426; called by muse, mutect2
- GCDH | c.1174A>G p.N392D | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1282266790, CM980883, COSV53367544; called by muse, mutect2, varscan2
- GCK | c.1264C>T p.R422W | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.98); catalogued as rs1208845035; called by muse, mutect2, varscan2
- GDF5 | c.1110T>G p.Y370* | Nonsense Mutation (SNP) | VAF 6/128 reads (5%) | catalogued as COSV100976959; called by muse, mutect2
- GLI3 | c.1153C>A p.P385T | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV67885653; called by muse, mutect2, varscan2
- GM2A | c.23C>A p.P8H | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as rs1314350384; called by muse, mutect2
- GNG12 | c.202del p.T68Lfs*22 | Frame Shift Del (DEL) | VAF 20/68 reads (29%) | catalogued as rs1022402829; called by mutect2, pindel, varscan2
- GOLGA4 | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 57/184 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs373660326; called by muse, mutect2, varscan2
- GPLD1 | c.2488G>A p.G830R | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755235873; called by muse, mutect2
- GPR162 | c.245A>G p.D82G | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs150501521; called by muse, mutect2, varscan2
- GPR27 | c.833C>T p.T278M | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as rs773053190, COSV55203995; called by muse, mutect2, varscan2
- GPR32 | c.973G>C p.E325Q | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.688); catalogued as rs1377589392, COSV99567358; called by muse, mutect2
- GPR88 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59290976; called by muse, mutect2
- GPRASP2 | c.1093A>G p.R365G | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100176924; called by muse, mutect2
- GPX2 | c.511C>A p.R171S | Missense Mutation (SNP) | VAF 49/184 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as COSV63036412; called by muse, mutect2, varscan2
- GRB7 | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.045); catalogued as rs767271125, COSV58448190; called by muse, mutect2, varscan2
- GSR | c.1075G>A p.V359I | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs138721223; called by muse, mutect2, varscan2
- GSR | c.607A>G p.M203V | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs758849140, COSV55321475; called by muse, mutect2, varscan2
- GTF3C1 | c.2299del p.S767Vfs*7 | Frame Shift Del (DEL) | VAF 38/126 reads (30%) | catalogued as rs1231771183; called by mutect2, pindel, varscan2
- GTSF1L | c.363del p.P122Lfs*50 | Frame Shift Del (DEL) | VAF 30/114 reads (26%) | catalogued as rs1568892529; called by mutect2, pindel, varscan2
- HASPIN | c.1909G>A p.A637T | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53997274; called by muse, mutect2, varscan2
- HAUS6 | c.2442A>T p.E814D | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as COSV100997895; called by muse, mutect2, varscan2
- HCAR2 | c.781T>G p.S261A | Missense Mutation (SNP) | VAF 71/551 reads (13%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as COSV61025128; called by muse, mutect2, varscan2
- HCFC1 | c.1648G>A p.A550T | Missense Mutation (SNP) | VAF 61/181 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60074040; called by muse, mutect2, varscan2
- HCFC1R1 | c.249del p.M84* | Frame Shift Del (DEL) | VAF 18/47 reads (38%) | catalogued as rs746547303; called by mutect2, pindel, varscan2
- HECA | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 78/207 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760164332, COSV62768949; called by muse, mutect2, varscan2
- HEPACAM | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs549252759, COSV53430756, COSV53432474; called by muse, mutect2, varscan2
- HERC2 | c.3853-1G>T p.X1285_splice | Splice Site (SNP) | VAF 42/144 reads (29%) | catalogued as COSV99876411; called by muse, mutect2, varscan2
- HEXD | c.1061+4A>G | Splice Region (SNP) | VAF 20/49 reads (41%) | catalogued as COSV60064578; called by muse, mutect2, varscan2
- HIP1R | c.2952+6C>T | Splice Region (SNP) | VAF 24/62 reads (39%) | catalogued as rs765219550; called by muse, mutect2, varscan2
- HK2 | c.1294C>T p.R432W | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs148796379; called by muse, mutect2, varscan2
- HMGN5 | c.534del p.G179Vfs*48 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | catalogued as rs1556033122; called by mutect2, pindel, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 34/96 reads (35%) | catalogued as rs761272507; called by mutect2, varscan2
- HOMEZ | c.1127del p.L376Yfs*14 | Frame Shift Del (DEL) | VAF 24/212 reads (11%) | catalogued as rs755016625; called by mutect2, varscan2
- HOXC13 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 59/126 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54498379; called by muse, mutect2, varscan2
- HS6ST3 | c.473del p.G158Afs*9 | Frame Shift Del (DEL) | VAF 39/128 reads (30%) | catalogued as rs753365436; called by mutect2, pindel, varscan2
- HSPA4L | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs200226261; called by muse, mutect2, varscan2
- HTR1A | c.731C>A p.A244E | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.113); catalogued as COSV100109348; called by muse, mutect2, varscan2
- HTR1D | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs780794417; called by muse, mutect2, varscan2
- HUWE1 | c.10063C>T p.R3355W | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs782740424; called by muse, mutect2, varscan2
- IFI16 | c.1484G>A p.S495N | Missense Mutation (SNP) | VAF 168/540 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.063); catalogued as COSV55535682; called by muse, mutect2, varscan2
- IFI27L2 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.803); catalogued as rs763009285, COSV53128793; called by muse, mutect2, varscan2
- IFI44 | c.240del p.F80Lfs*13 | Frame Shift Del (DEL) | VAF 35/203 reads (17%) | catalogued as COSV66074062, COSV66074655; called by mutect2, pindel, varscan2
- IFNB1 | c.236C>T p.T79I | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1368191578, COSV101207811; called by muse, mutect2, varscan2
- IFNLR1 | c.823C>A p.P275T | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.087); catalogued as rs1185549444; called by muse, mutect2, varscan2
- IFT80 | c.1546G>A p.D516N | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as rs1328308378; called by muse, mutect2, varscan2
- IGDCC4 | c.2273C>T p.A758V | Missense Mutation (SNP) | VAF 54/175 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.362); catalogued as rs758067780; called by muse, mutect2, varscan2
- IGF2 | c.686del p.P229Qfs*27 (on ENST00000434045 / NM_001127598.3; = p.P173Qfs*27 on NM_000612.6) | Frame Shift Del (DEL) | VAF 39/121 reads (32%) | catalogued as rs755455183; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- IGF2R | c.3221C>T p.A1074V | Missense Mutation (SNP) | VAF 52/159 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199563373, COSV63630913; called by muse, mutect2, varscan2
- IGFBP2 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV52080618; called by muse, mutect2, varscan2
- IGHMBP2 | c.1444G>T p.E482* | Nonsense Mutation (SNP) | VAF 18/66 reads (27%) | catalogued as COSV54824791; called by mutect2, varscan2
- IGHV2OR16-5 | c.89T>C p.L30P | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs779129755; called by mutect2, varscan2
- IGSF8 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT tolerated (0.74); PolyPhen benign (0.056); catalogued as rs1302405878; called by muse, mutect2, varscan2
- IL18RAP | c.119A>C p.E40A | Missense Mutation (SNP) | VAF 15/232 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99962381; called by muse, mutect2
- IL22RA1 | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as rs750435511; called by muse, mutect2
- INO80 | c.3419G>T p.R1140M | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62739037; called by muse, mutect2, varscan2
- INSYN1 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773537559, COSV101138675; called by muse, mutect2, varscan2
- INTS12 | c.41del p.L14* | Frame Shift Del (DEL) | VAF 16/51 reads (31%) | catalogued as COSV60863912; called by pindel, varscan2
- IRF2 | c.187G>T p.G63* | Nonsense Mutation (SNP) | VAF 28/73 reads (38%) | catalogued as COSV66928695; called by muse, mutect2, varscan2
- IRF8 | c.569C>T p.T190M | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs140514602, COSV99236813; called by muse, mutect2, varscan2
- ISG15 | c.109G>A p.G37S | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.283); catalogued as rs752866829, COSV65106524; called by muse, mutect2, varscan2
- ITGA4 | c.120C>A p.S40R | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.443); catalogued as COSV99276399; called by muse, mutect2, varscan2
- ITIH6 | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 42/165 reads (25%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.608); catalogued as rs758361448, COSV54489981; called by muse, mutect2, varscan2
- ITM2C | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs760386716, COSV99072585; called by muse, mutect2, varscan2
- ITSN1 | c.4273C>T p.R1425W | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs187930521, COSV101182079; called by muse, mutect2, varscan2
- JPT2 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1300027912, COSV99936238; called by muse, mutect2, varscan2
- JRKL | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1463807331; called by muse, mutect2, varscan2
- JSRP1 | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.094); catalogued as rs539381800; called by muse, mutect2, varscan2
- KALRN | c.4198C>T p.R1400W | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775145320, COSV53756060, COSV53780259, COSV99565542; called by muse, mutect2, varscan2
- KANSL1 | c.2470C>T p.R824* | Nonsense Mutation (SNP) | VAF 58/150 reads (39%) | catalogued as COSV52264743; called by muse, mutect2, varscan2
- KATNB1 | c.1231G>A p.A411T | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs782208957, COSV65551196; called by muse, mutect2, varscan2
- KCNA5 | c.1704del p.T569Pfs*15 | Frame Shift Del (DEL) | VAF 13/43 reads (30%) | catalogued as rs1565466174, COSV99363705; called by mutect2, pindel, varscan2
- KCNB2 | c.435del p.E146Nfs*3 | Frame Shift Del (DEL) | VAF 26/83 reads (31%) | catalogued as rs752059864; called by mutect2, varscan2
- KCNH3 | c.1927G>A p.D643N | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1266126517, COSV57790216, COSV57791795; called by muse, mutect2, varscan2
- KCNH6 | c.2176dup p.R726Pfs*16 | Frame Shift Ins (INS) | VAF 36/120 reads (30%) | catalogued as rs1312956554; called by mutect2, pindel, varscan2
- KCTD9 | c.304A>G p.T102A | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55340628; called by muse, mutect2
- KDM2B | c.77del p.K26Rfs*81 | Frame Shift Del (DEL) | VAF 21/51 reads (41%) | catalogued as rs782541016; called by mutect2, pindel, varscan2
- KDM5A | c.3597del p.G1200Dfs*9 | Frame Shift Del (DEL) | VAF 26/76 reads (34%) | catalogued as rs771545848; called by mutect2, varscan2
- KIAA0319 | c.1349C>T p.T450M | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs774205815; called by muse, mutect2, varscan2
- KIAA1522 | c.2927del p.P976Hfs*70 (on ENST00000373480 / NM_001198972.2; = p.P1035Hfs*70 on NM_020888.3) | Frame Shift Del (DEL) | VAF 57/159 reads (36%) | catalogued as COSV99615233; called by mutect2, pindel, varscan2
- KIAA2026 | c.2187del p.A730Qfs*26 | Frame Shift Del (DEL) | VAF 20/45 reads (44%) | catalogued as rs749990720; called by mutect2, varscan2
- KIDINS220 | c.3314C>T p.T1105M | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as rs199990643; called by muse, mutect2, varscan2
- KIDINS220 | c.1960del p.T654Hfs*34 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | catalogued as COSV56750986; called by mutect2, pindel, varscan2
- KIF13A | c.1967C>T p.A656V | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as rs768744386, COSV52445487; called by muse, mutect2, varscan2
- KLHL26 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.044); catalogued as COSV99963119; called by muse, mutect2
- KLHL42 | c.1194del p.C399Vfs*44 | Frame Shift Del (DEL) | VAF 26/139 reads (19%) | catalogued as rs749194179; called by mutect2, pindel, varscan2
- KMT2B | c.3602del p.P1201Rfs*154 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | catalogued as COSV55870773; called by mutect2, pindel, varscan2
- KMT2C | c.3184G>T p.A1062S | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.994); catalogued as COSV100075937; called by muse, varscan2
- KMT5A | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs758323252; called by muse, mutect2, varscan2
- KNCN | c.361del p.A121Lfs*111 (on ENST00000481882 / NM_001322255.2; = p.A98Lfs*? on NM_001097611.1) | Frame Shift Del (DEL) | VAF 46/163 reads (28%) | catalogued as rs539443691; called by mutect2, pindel, varscan2
- KNOP1 | c.652del p.I218Sfs*41 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs764099275; called by mutect2, varscan2
- KRT16 | c.197del p.G66Afs*54 | Frame Shift Del (DEL) | VAF 11/52 reads (21%) | catalogued as rs1555573913; called by mutect2, pindel, varscan2
- KRT6A | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 75/269 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs200254647, COSV58106549; called by muse, mutect2, varscan2
- KRTAP4-1 | c.196C>T p.H66Y | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs775580976; called by muse, mutect2, varscan2
- KSR2 | c.2663C>T p.T888I | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV56679768; called by muse, mutect2, varscan2
- KTN1 | c.3948G>A p.T1316= (on ENST00000395314 / NM_001271014.2; = p.T1259= on NM_004986.4) | Splice Region (SNP) | VAF 11/24 reads (46%) | catalogued as rs752354703, COSV58539850; called by muse, mutect2, varscan2
- LAMC3 | c.2120G>A p.C707Y | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1372053801; called by muse, mutect2, varscan2
- LAMC3 | c.3815C>T p.A1272V | Missense Mutation (SNP) | VAF 32/212 reads (15%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs146180154, COSV62653367; called by muse, mutect2, varscan2
- LARGE1 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as rs1040172997; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 18/46 reads (39%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LGR5 | c.443A>G p.N148S | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1430310273, COSV57006470; called by muse, mutect2, varscan2
- LIPJ | c.396A>C p.Q132H | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64245752; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LMNTD2 | c.1069C>T p.Q357* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as rs1305079628; called by muse, mutect2
- LMOD1 | c.1009G>A p.V337I | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as rs1219690493, COSV66173242; called by muse, mutect2, varscan2
- LOXL3 | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1474992303; called by muse, mutect2, varscan2
- LPAR4 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.279); catalogued as COSV70912654; called by muse, mutect2, varscan2
- LRIG2 | c.2620G>A p.A874T | Missense Mutation (SNP) | VAF 45/290 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as rs1183191462; called by muse, mutect2, varscan2
- LRP12 | c.1351del p.C451Afs*37 | Frame Shift Del (DEL) | VAF 23/90 reads (26%) | catalogued as rs35928649; called by mutect2, pindel, varscan2
- LRRC31 | c.1624del p.R542Efs*37 | Frame Shift Del (DEL) | VAF 10/112 reads (9%) | catalogued as rs748577734; called by mutect2, pindel
- LRRC7 | c.2917del p.L973* (on ENST00000651989 / NM_001370785.2; = p.L940* on NM_001330635.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 41/140 reads (29%) | catalogued as COSV50466223; called by mutect2, pindel, varscan2
- LUC7L3 | c.1165dup p.S389Kfs*2 | Frame Shift Ins (INS) | VAF 59/218 reads (27%) | catalogued as rs1229438198; called by mutect2, varscan2
- LVRN | c.1390del p.S464Lfs*15 | Frame Shift Del (DEL) | VAF 19/103 reads (18%) | catalogued as rs756702147; called by mutect2, pindel, varscan2
- LY75 | c.4235del p.K1412Rfs*2 | Frame Shift Del (DEL) | VAF 37/95 reads (39%) | catalogued as rs1301982151; called by mutect2, pindel, varscan2
- LZTS2 | c.303del p.S102Afs*41 | Frame Shift Del (DEL) | VAF 44/136 reads (32%) | catalogued as rs1460451498; called by mutect2, pindel, varscan2
- MACO1 | c.306del p.F102Lfs*47 | Frame Shift Del (DEL) | VAF 21/44 reads (48%) | catalogued as rs752439249; called by mutect2, varscan2
- MAGEL2 | c.1805C>T p.T602M | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated, low confidence (0.28); catalogued as rs761204158, COSV100046175; called by muse, varscan2
- MAGI3 | c.3734del p.N1245Ifs*65 | Frame Shift Del (DEL) | VAF 25/95 reads (26%) | catalogued as rs1194613351; called by mutect2, pindel, varscan2
- MAK | c.878C>T p.S293L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.075); catalogued as rs773485283, COSV100504777; called by muse, mutect2, varscan2
- MAP10 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765529081, COSV69363988; called by muse, mutect2, varscan2
- MARCO | c.899A>G p.Q300R | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.354); catalogued as rs1166398537; called by muse, mutect2, varscan2
- MATN2 | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs377009254; called by muse, mutect2, varscan2
- MCF2L | c.2150G>A p.R717K (on ENST00000375608; = p.R685K on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs758863800, COSV99996056; called by muse, mutect2
- MDN1 | c.11208G>T p.E3736D | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.071); catalogued as rs754776073; called by muse, mutect2, varscan2
- MDN1 | c.5966del p.K1989Rfs*65 | Frame Shift Del (DEL) | VAF 14/39 reads (36%) | catalogued as rs750092100; called by mutect2, varscan2
- ME3 | c.1352C>T p.T451M | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs763282991, COSV62774533, COSV62774628; called by muse, mutect2, varscan2
- MECOM | c.1839del p.G614Efs*30 (on ENST00000468789 / NM_001105078.4; = p.G802Efs*30 on NM_004991.4) | Frame Shift Del (DEL) | VAF 44/154 reads (29%) | catalogued as rs773080349; called by mutect2, pindel, varscan2
- MEF2C | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as rs755436703, CM123288; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MFSD11 | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.754); catalogued as rs1458315882, COSV60622866; called by muse, mutect2, varscan2
- MGA | c.7139+1G>A p.X2380_splice (on ENST00000219905 / NM_001164273.1; = p.X2171_splice on NM_001080541.2) | Splice Site (SNP) | VAF 10/101 reads (10%) | catalogued as COSV54963267; called by muse, mutect2, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 11/77 reads (14%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MLLT10 | c.1231del p.V411* | Frame Shift Del (DEL) | VAF 35/141 reads (25%) | catalogued as rs747811015; called by mutect2, pindel, varscan2
- MMP24 | c.1679G>A p.R560H | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1190018879, COSV55770346, COSV55773901; called by muse, mutect2, varscan2
- MPHOSPH8 | c.1452G>T p.K484N | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.914); catalogued as COSV64056141; called by muse, mutect2, varscan2
- MPP7 | c.1129G>A p.V377M | Missense Mutation (SNP) | VAF 66/163 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.829); catalogued as rs578191058; called by muse, mutect2, varscan2
- MRPL58 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 68/161 reads (42%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.949); catalogued as rs375880126; called by muse, mutect2, varscan2
- MRTFA | c.1220dup p.V408Sfs*9 | Frame Shift Ins (INS) | VAF 26/58 reads (45%) | catalogued as rs34028511; called by mutect2, varscan2
- MSLNL | c.1086G>T p.Q362H | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV53503801; called by muse, mutect2, varscan2
- MSR1 | c.1163G>A p.C388Y | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1481887954; called by muse, mutect2, varscan2
- MTO1 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.081); catalogued as rs370046018; called by muse, mutect2, varscan2
- MTOR | c.2976G>T p.Q992H | Missense Mutation (SNP) | VAF 74/228 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); catalogued as COSV63880279; called by muse, mutect2, varscan2
- MTR | c.342C>A p.A114= | Splice Region (SNP) | VAF 57/165 reads (35%) | catalogued as COSV63969872; called by muse, mutect2, varscan2
- MTREX | c.239C>A p.P80H | Missense Mutation (SNP) | VAF 80/220 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.372); catalogued as COSV100044700, COSV57925864; called by muse, mutect2, varscan2
- MUC21 | c.28C>A p.L10I | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.732); catalogued as rs146848216, COSV104426672, COSV66221576; called by muse, mutect2, varscan2
- MYBPC2 | c.1718del p.P573Lfs*7 | Frame Shift Del (DEL) | VAF 36/147 reads (24%) | catalogued as rs1477783157; called by mutect2, pindel, varscan2
- MYC | c.176C>T p.P59L (on ENST00000377970; = p.P74L on NM_002467.6) | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1294281543, COSV52368162, COSV52368882, COSV52375206; called by muse, mutect2, varscan2
- MYCBPAP | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV60406845; called by muse, mutect2, varscan2
- MYCL | c.307G>C p.E103Q (on ENST00000372816 / NM_001033081.3; = p.E133Q on NM_005376.5) | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.999); catalogued as COSV100862283; called by muse, varscan2
- MYH10 | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52595762; called by muse, mutect2, varscan2
- MYH13 | c.2260G>A p.D754N | Missense Mutation (SNP) | VAF 65/215 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs369919760; called by muse, mutect2, varscan2
- MYO18A | c.4183G>A p.D1395N | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV62868757; called by muse, varscan2
- MYRIP | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs367917395; called by muse, mutect2, varscan2
- MYSM1 | c.1516C>T p.R506* | Nonsense Mutation (SNP) | VAF 8/80 reads (10%) | catalogued as rs780757165; called by mutect2, varscan2
- MYT1L | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.781); catalogued as rs778352465, COSV101220766; called by muse, mutect2, varscan2
- NADK2 | c.1175G>A p.R392H (on ENST00000381937 / NM_001085411.3; = p.R229H on NM_153013.4) | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as rs772840407, COSV99237286; called by muse, mutect2, varscan2
- NAF1 | c.617G>A p.S206N | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.373); catalogued as rs562790761; called by muse, mutect2, varscan2
- NAGPA | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 24/76 reads (32%) | PolyPhen probably damaging (0.998); catalogued as rs918720031; called by muse, mutect2, varscan2
- NALCN | c.4577G>A p.G1526D | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.031); catalogued as COSV51966881; called by muse, mutect2, varscan2
- NALCN | c.4483C>T p.R1495W | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1485549287, COSV51921358; called by muse, mutect2, varscan2
- NARS1 | c.1565G>A p.R522Q | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56876486; called by muse, mutect2, varscan2
- NBEA | c.1903C>T p.R635C | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs779319414, COSV59832861; called by muse, mutect2, varscan2
- NBPF3 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as rs757791248, COSV59060453; called by muse, mutect2, varscan2
- NCAPG | c.2110-1G>T p.X704_splice | Splice Site (SNP) | VAF 13/65 reads (20%) | catalogued as COSV99266147; called by muse, mutect2, varscan2
- NCBP2 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.176); catalogued as rs772956368, COSV58318266; called by muse, mutect2, varscan2
- NEB | c.12920C>T p.S4307L | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1560020231, COSV51428818; called by muse, mutect2, varscan2
- NEK5 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62880685; called by muse, mutect2, varscan2
- NEK6 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs183673274; called by muse, mutect2, varscan2
- NES | c.4577C>T p.A1526V | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV63963312; called by muse, mutect2, varscan2
- NETO1 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV55006268; called by muse, mutect2, varscan2
- NEXN | c.1399del p.I467* | Frame Shift Del (DEL) | VAF 54/151 reads (36%) | catalogued as rs1365488625; called by mutect2, pindel, varscan2
- NF1 | c.8160G>T p.K2720N (on ENST00000358273 / NM_001042492.3; = p.K2699N on NM_000267.3) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as COSV62208176; called by muse, mutect2
- NFATC2 | c.2366G>A p.G789D | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1317622208; called by muse, mutect2, varscan2
- NFE2L1 | c.2237G>A p.G746D | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62583836; called by muse, mutect2, varscan2
- NIPA1 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as COSV61680180; called by muse, mutect2, varscan2
- NKAPL | c.165G>A p.W55* | Nonsense Mutation (SNP) | VAF 25/99 reads (25%) | catalogued as COSV100642529; called by muse, mutect2, varscan2
- NLRC5 | c.5543A>G p.E1848G | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs754664322; called by muse, mutect2, varscan2
- NLRP12 | c.2188del p.V730* | Frame Shift Del (DEL) | VAF 42/139 reads (30%) | catalogued as rs771632319; called by mutect2, pindel, varscan2
- NLRP2 | c.3113del p.N1038Tfs*4 | Frame Shift Del (DEL) | VAF 21/57 reads (37%) | catalogued as rs745782532; called by mutect2, pindel, varscan2
- NOL8 | c.2146G>A p.G716S | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748873347, COSV62635939; called by muse, mutect2, varscan2
- NOLC1 | c.840del p.K280Nfs*3 | Frame Shift Del (DEL) | VAF 10/90 reads (11%) | catalogued as rs759637346; called by mutect2, varscan2
- NONO | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV52135765; called by muse, mutect2, varscan2
- NOP14 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.266); catalogued as COSV58625163; called by muse, mutect2
- NOP2 | c.2410_2411insT p.R804Mfs*13 (on ENST00000322166 / NM_001258308.2; = p.R800Mfs*13 on NM_006170.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 35/112 reads (31%) | catalogued as COSV100351339; called by mutect2, pindel, varscan2
- NOS2 | c.2008C>T p.R670C | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs200815966, COSV100569655; called by muse, mutect2, varscan2
- NPAP1 | c.550G>T p.E184* | Nonsense Mutation (SNP) | VAF 23/76 reads (30%) | catalogued as COSV61504791; called by muse, mutect2, varscan2
- NPHP4 | c.2768G>A p.R923H | Missense Mutation (SNP) | VAF 66/183 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs775765661; called by muse, mutect2, varscan2
- NPTX1 | c.573del p.R192Gfs*14 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | catalogued as COSV100151049; called by mutect2, pindel
- NRDE2 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768869559, COSV62963962; called by muse, mutect2, varscan2
- NRP2 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.488); catalogued as COSV99785463; called by muse, mutect2
- NTF4 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs377553005; called by muse, mutect2, varscan2
- NTMT1 | c.542G>T p.S181I | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52965292; called by muse, mutect2, varscan2
- NTRK3 | c.947G>T p.R316L | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV58111825; called by muse, mutect2, varscan2
- NUGGC | c.1415C>T p.T472I | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV58436186; called by muse, mutect2
- NUP214 | c.4133dup p.V1379Gfs*60 | Frame Shift Ins (INS) | VAF 46/114 reads (40%) | catalogued as rs780417788; called by mutect2, varscan2
- OBSL1 | c.2452C>T p.H818Y | Missense Mutation (SNP) | VAF 80/212 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); catalogued as COSV54707301; called by muse, mutect2, varscan2
- OR2AE1 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs534917452, COSV100318270; called by muse, mutect2, varscan2
- OR4M1 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 61/277 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs376190089; called by muse, mutect2, varscan2
- OR4P4 | c.315del p.F105Lfs*4 | Frame Shift Del (DEL) | VAF 13/54 reads (24%) | catalogued as rs748398423; called by mutect2, pindel, varscan2
- OR51B4 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 95/275 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as rs747263622; called by muse, mutect2, varscan2
- OR6K3 | c.463del p.R155Gfs*23 (on ENST00000368146; = p.R139Gfs*23 on NM_001005327.2) | Frame Shift Del (DEL) | VAF 32/126 reads (25%) | catalogued as rs760987507, COSV63745721, COSV63746101; called by mutect2, pindel, varscan2
- OR6M1 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV100484049; called by muse, mutect2, varscan2
- OR9G1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756704219, COSV100380538, COSV56454460; called by muse, mutect2, varscan2
- OTOA | c.1441C>T p.R481C (on ENST00000286149; = p.R467C on NM_144672.4) | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.613); catalogued as rs757720270, COSV53750032; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OXCT2 | c.1526T>A p.L509H | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59594121; called by muse, varscan2
- OXER1 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as rs780052387, COSV99685605; called by muse, mutect2, varscan2
- PADI3 | c.991G>A p.G331S | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.59); catalogued as rs773298347, COSV64934769; called by muse, mutect2, varscan2
- PAPLN | c.3218del p.P1073Qfs*32 (on ENST00000554301; = p.P1046Qfs*32 on NM_173462.4) | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | catalogued as COSV99390248; called by mutect2, varscan2
- PATL1 | c.1564A>C p.T522P | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as COSV55689504; called by muse, mutect2, varscan2
- PCDH11X | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 18/558 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV100007573; called by muse, mutect2
- PCDH17 | c.845dup p.S283Qfs*6 | Frame Shift Ins (INS) | VAF 25/158 reads (16%) | catalogued as rs1480073728; called by mutect2, pindel, varscan2
- PCDH7 | c.982C>A p.L328M | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100688598; called by muse, mutect2
- PCDH7 | c.1490C>T p.A497V | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.201); catalogued as rs898058102; called by muse, mutect2
- PCDHA1 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs1554117407, COSV65375967; called by muse, mutect2, varscan2
- PCDHA11 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); catalogued as COSV56489775; called by muse, mutect2, varscan2
- PCDHA8 | c.2048C>T p.S683L | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs372061063; called by muse, mutect2, varscan2
- PCDHGA10 | c.665del p.G222Vfs*13 | Frame Shift Del (DEL) | VAF 32/85 reads (38%) | catalogued as COSV53900560; called by mutect2, pindel, varscan2
- PCDHGA12 | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.605); catalogued as COSV52750613; called by muse, mutect2, varscan2
- PCED1B | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as rs912319420, COSV71395778; called by muse, mutect2, varscan2
- PCED1B | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as COSV71395361; called by muse, mutect2, varscan2
- PCGF2 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as rs968126661; called by muse, mutect2, varscan2
- PCLO | c.9224A>G p.Q3075R | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.288); catalogued as COSV61644211; called by muse, mutect2, varscan2
- PCNX1 | c.5209G>A p.D1737N | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53101403; called by muse, mutect2, varscan2
- PCSK7 | c.739G>A p.V247M | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs760392010; called by muse, mutect2, varscan2
- PDE6H | c.159G>A p.M53I | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.389); catalogued as rs1333663895; called by muse, mutect2, varscan2
- PDE8B | c.1097G>A p.G366D | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as rs1470494378, COSV53737761; called by muse, mutect2, varscan2
- PDS5B | c.3954del p.K1318Nfs*76 | Frame Shift Del (DEL) | VAF 12/78 reads (15%) | catalogued as rs747131399; called by mutect2, varscan2
- PEAR1 | c.3012del p.G1005Afs*57 | Frame Shift Del (DEL) | VAF 29/105 reads (28%) | catalogued as rs750264783; called by mutect2, pindel, varscan2
- PELO | c.1039T>G p.S347A | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50885764; called by muse, mutect2, varscan2
- PFKP | c.1785del p.L596Sfs*27 | Frame Shift Del (DEL) | VAF 20/76 reads (26%) | catalogued as rs747416036; called by mutect2, pindel
- PHAX | c.553dup p.M185Nfs*32 | Frame Shift Ins (INS) | VAF 31/83 reads (37%) | catalogued as rs1447045455; called by mutect2, varscan2
- PHF13 | c.458C>T p.T153M | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs182208081, COSV50011299; called by muse, mutect2, varscan2
- PHF20L1 | c.1721del p.K574Rfs*28 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as rs772333737; called by mutect2, varscan2
- PHF21A | c.1955del p.P652Lfs*104 (on ENST00000418153 / NM_001101802.3; = p.P606Lfs*104 on NM_016621.5 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 17/47 reads (36%) | catalogued as rs761575760; called by mutect2, pindel, varscan2
- PHKB | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs776018181, COSV54520315; called by muse, mutect2, varscan2
- PIGS | c.1145T>C p.M382T | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV52025124; called by muse, mutect2
- PIK3C2B | c.1680del p.C561Afs*18 | Frame Shift Del (DEL) | VAF 21/52 reads (40%) | catalogued as rs1375341411; called by mutect2, pindel, varscan2
- PIK3R1 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 68/162 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.988); catalogued as rs765266397; called by muse, mutect2, varscan2
- PIK3R2 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 55/160 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as rs768743781, COSV99717247; called by muse, mutect2, varscan2
- PIM2 | c.39dup p.G14Rfs*27 | Frame Shift Ins (INS) | VAF 37/157 reads (24%) | catalogued as rs782496935; called by mutect2, pindel, varscan2
- PISD | c.701C>T p.A234V (on ENST00000439502 / NM_001326412.1; = p.A200V on NM_014338.3) | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as rs760199435; called by muse, mutect2, varscan2
- PITPNM3 | c.1850G>A p.R617Q | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs754791081, COSV52592962; called by muse, mutect2, varscan2
- PKDREJ | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs1010985979; called by muse, mutect2, varscan2
- PKN2 | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV60132532; called by muse, mutect2, varscan2
- PKP2 | c.1368del p.K456Nfs*3 | Frame Shift Del (DEL) | VAF 27/74 reads (36%) | catalogued as rs1393661338, CD061458; called by mutect2, pindel, varscan2
- PLAAT4 | c.483del p.A162Rfs*56 | Frame Shift Del (DEL) | VAF 44/108 reads (41%) | catalogued as rs745860467; called by mutect2, varscan2
- PLB1 | c.4361G>A p.R1454H | Missense Mutation (SNP) | VAF 60/164 reads (37%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs769466567, COSV59822628; called by muse, mutect2, varscan2
- PLEKHA2 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs1050698413, COSV66242246; called by muse, mutect2
- PLEKHA5 | c.2639C>T p.T880M | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.964); catalogued as rs572731528, COSV54696078; called by muse, mutect2, varscan2
- PLEKHA7 | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs200063816; called by muse, mutect2, varscan2
- PLS1 | c.1796A>G p.Y599C | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772376016; called by muse, mutect2, varscan2
- PLVAP | c.972G>T p.K324N | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.697); catalogued as COSV99391644; called by muse, mutect2, varscan2
- PLXNB2 | c.67C>A p.R23S | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.09); catalogued as COSV63782192; called by muse, mutect2, varscan2
- PLXNB3 | c.4100G>A p.R1367H | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs782100931, COSV62799959; called by muse, mutect2, varscan2
- PLXNB3 | c.5262-1G>A p.X1754_splice | Splice Site (SNP) | VAF 75/175 reads (43%) | catalogued as rs1557065067, COSV100737832; called by muse, mutect2, varscan2
- PNP | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.183); catalogued as rs150531909; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLI | c.1409T>C p.M470T | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as COSV54190185; called by muse, mutect2
- POLR1A | c.1616G>A p.C539Y | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs1444830894; called by muse, mutect2, varscan2
- POM121C | c.1508A>G p.Q503R (on ENST00000607367; = p.Q261R on NM_001099415.3) | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as COSV57546958, COSV57548289; called by muse, mutect2, varscan2
- POP1 | c.2254del p.T752Lfs*12 | Frame Shift Del (DEL) | VAF 28/103 reads (27%) | catalogued as rs868622083, COSV62893071; called by mutect2, pindel, varscan2
- PPFIA4 | c.2249G>A p.R750H (on ENST00000447715; = p.R751H on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 133/360 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV99690709; called by muse, mutect2, varscan2
- PPM1F | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1395693423; called by muse, mutect2, varscan2
- PPP1R3F | c.1793C>T p.S598L | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs148829919, COSV50019616, COSV50020480; called by muse, mutect2, varscan2
- PPP6R2 | c.2103del p.P703Lfs*29 (on ENST00000216061 / NM_001365836.1; = p.P676Lfs*29 on NM_014678.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 23/64 reads (36%) | catalogued as COSV53292437; called by mutect2, pindel, varscan2
- PRDM14 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1326344609; called by muse, mutect2, varscan2
- PRKAG3 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as rs141188865; called by muse, mutect2, varscan2
- PRKCH | c.1762T>C p.F588L | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.136); catalogued as COSV60647884; called by muse, mutect2
- PRMT3 | c.1346C>T p.T449M | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765904610; called by muse, mutect2, varscan2
- PRR23C | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.776); catalogued as COSV101356475; called by muse, mutect2, varscan2
- PRRC2B | c.6226C>T p.L2076= | Splice Region (SNP) | VAF 45/124 reads (36%) | catalogued as rs1483102784, COSV57645504; called by muse, mutect2, varscan2
- PRX | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs757322355; called by muse, mutect2, varscan2
- PTK2 | c.2431C>T p.R811C | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs988016005; called by muse, mutect2, varscan2
- PTK2B | c.1836C>T p.A612= | Splice Region (SNP) | VAF 32/97 reads (33%) | catalogued as rs376666218; called by muse, mutect2, varscan2
- PTPN9 | c.752T>C p.L251P | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV60723298; called by muse, mutect2
- PTPRF | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.756); catalogued as rs150660901; called by muse, mutect2, varscan2
- PTPRF | c.3443C>T p.T1148M | Missense Mutation (SNP) | VAF 161/421 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.165); catalogued as rs774648724; called by muse, mutect2, varscan2
- PXDN | c.2371G>A p.A791T | Missense Mutation (SNP) | VAF 69/218 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs767012980, COSV99414118; called by muse, varscan2
- PXMP4 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as rs182672515, COSV99459289; called by muse, mutect2, varscan2
- QTRT2 | c.827C>A p.P276H | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55560589; called by muse, mutect2
- R3HDM1 | c.2812C>T p.Q938* | Nonsense Mutation (SNP) | VAF 98/297 reads (33%) | catalogued as COSV51526690; called by muse, mutect2, varscan2
- RABGAP1L | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV52280518; called by muse, mutect2, varscan2
- RAI1 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1267382743, COSV55394793; called by muse, mutect2, varscan2
- RAI1 | c.3103del p.Q1035Rfs*29 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | catalogued as rs774789734; called by mutect2, varscan2
- RALGAPA1 | c.4406G>A p.S1469N | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51887454; called by muse, mutect2, varscan2
- RALGAPA1 | c.939G>A p.W313* | Nonsense Mutation (SNP) | VAF 43/111 reads (39%) | catalogued as COSV51887462; called by muse, mutect2, varscan2
- RALGAPB | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); catalogued as rs6100055; called by muse, mutect2, varscan2
- RALGPS1 | c.262G>T p.A88S | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.083); catalogued as rs1158612554; called by muse, mutect2, varscan2
- RARA | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 85/238 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.647); catalogued as COSV54193537; called by muse, mutect2, varscan2
- RASAL1 | c.901T>C p.C301R | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); catalogued as COSV55653958; called by muse, mutect2
- RASAL2 | c.722del p.K241Rfs*7 | Frame Shift Del (DEL) | VAF 12/111 reads (11%) | catalogued as rs771909008; called by mutect2, varscan2
- RAVER1 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 57/134 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs754877220; called by muse, mutect2, varscan2
- RBIS | c.65del p.N22Tfs*18 | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | catalogued as rs752886571; called by mutect2, pindel, varscan2
- RBMX | c.1141C>T p.R381* | Nonsense Mutation (SNP) | VAF 115/524 reads (22%) | catalogued as rs1462288141, COSV100284920; called by muse, mutect2, varscan2
- RC3H1 | c.2017C>T p.R673C | Missense Mutation (SNP) | VAF 78/231 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs773753006; called by muse, mutect2, varscan2
- RELB | c.1687C>T p.R563C | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.892); catalogued as rs770578374, COSV55509337; called by muse, mutect2, varscan2
- RELN | c.8920G>T p.G2974C | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59020304; called by muse, mutect2, varscan2
- RFX6 | c.1453G>A p.G485R | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs768220475; called by muse, mutect2, varscan2
- RFX7 | c.1655C>A p.P552H (on ENST00000559447 / NM_001368074.1; = p.P649H on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.088); catalogued as COSV57965502, COSV57966707; called by muse, mutect2
- RGPD4 | c.3219G>T p.E1073D | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV100736708; called by muse, mutect2
- RIF1 | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761686456, COSV99691050; called by muse, mutect2, varscan2
- RIMBP3 | c.4297G>A p.A1433T | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1389368890; called by mutect2, varscan2
- RIMS1 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.55); PolyPhen benign (0.054); catalogued as rs1344104997, COSV53445856; called by muse, mutect2, varscan2
- RIMS3 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.73); catalogued as COSV65503988; called by muse, varscan2
- RNASE10 | c.495del p.K165Nfs*11 | Frame Shift Del (DEL) | VAF 43/148 reads (29%) | catalogued as rs1401645182; called by mutect2, pindel, varscan2
- RNF128 | c.31del p.W11Gfs*4 | Frame Shift Del (DEL) | VAF 66/172 reads (38%) | catalogued as rs757038390; called by mutect2, varscan2
- RNF208 | c.490C>T p.H164Y | Missense Mutation (SNP) | VAF 77/214 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61288396; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 28/59 reads (47%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNF43 | c.1424C>A p.S475Y | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68456910; called by muse, varscan2
- RNFT2 | c.53G>T p.S18I | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV54339125; called by muse, mutect2, varscan2
- ROBO2 | c.3233dup p.V1079Sfs*22 | Frame Shift Ins (INS) | VAF 17/95 reads (18%) | catalogued as rs745519558; called by mutect2, varscan2
- ROBO3 | c.571dup p.R191Pfs*61 | Frame Shift Ins (INS) | VAF 12/32 reads (38%) | catalogued as rs756837590; ClinVar: uncertain significance; called by mutect2, varscan2
- ROBO3 | c.2798C>T p.P933L | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs201504479, COSV67301233; called by muse, mutect2, varscan2
- ROPN1B | c.130C>A p.L44M | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV52542628; called by muse, mutect2, varscan2
- RPA4 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as COSV61264023; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 14/22 reads (64%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPP30 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as rs768419490; called by muse, mutect2, varscan2
- RPS11 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 35/214 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as rs11549537, COSV54527032; called by muse, mutect2, varscan2
- RPTOR | c.2870C>T p.T957M | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs200514795, COSV60803320, COSV60803502; called by muse, mutect2, varscan2
- RTEL1 | c.2965C>T p.R989W | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs139221232, COSV100541536; called by muse, mutect2, varscan2
- RTKN2 | c.1348del p.I450Lfs*67 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs759252078; called by mutect2, varscan2
- RUBCNL | c.1631+2T>C p.X544_splice | Splice Site (SNP) | VAF 24/113 reads (21%) | catalogued as COSV100529338; called by muse, mutect2, varscan2
- RUNX2 | c.1385del p.G462Efs*22 (on ENST00000371438; = p.G440Efs*22 on NM_001015051.3) | Frame Shift Del (DEL) | VAF 40/132 reads (30%) | catalogued as rs1561822364, COSV61840797; called by mutect2, pindel, varscan2
- RXFP2 | c.2161del p.S721Vfs*9 | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | catalogued as rs761227490; called by mutect2, varscan2
- RXFP3 | c.1194G>T p.K398N | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100347471; called by muse, varscan2
- RYR3 | c.3815C>T p.T1272M | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.418); catalogued as rs200621978, CM137597; called by muse, mutect2, varscan2
- S100A7 | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 68/183 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1038529990, COSV100906742; called by muse, mutect2, varscan2
- SAMD3 | c.186del p.K62Nfs*9 | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | catalogued as rs770241311; called by mutect2, pindel, varscan2
- SAMSN1 | c.710G>T p.R237M | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs376699090; called by muse, mutect2, varscan2
- SASH3 | c.953-1G>A p.X318_splice | Splice Site (SNP) | VAF 58/186 reads (31%) | catalogued as COSV63556121; called by muse, mutect2, varscan2
- SBNO1 | c.3416del p.N1139Mfs*9 (on ENST00000420886; = p.N1138Mfs*9 on NM_018183.5) | Frame Shift Del (DEL) | VAF 40/115 reads (35%) | catalogued as rs765867975; called by mutect2, varscan2
- SCAF11 | c.3731G>A p.R1244H | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs762262046, COSV101014148, COSV65475310; called by muse, mutect2, varscan2
- SCAF8 | c.710C>T p.T237M | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs147186513; called by muse, mutect2, varscan2
- SCN11A | c.1472del p.K491Sfs*5 | Frame Shift Del (DEL) | VAF 46/79 reads (58%) | catalogued as rs765136101; called by mutect2, pindel, varscan2
- SCN1A | c.5621G>A p.R1874Q (on ENST00000303395 / NM_001202435.3; = p.R1863Q on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1060502186; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN8A | c.2975G>A p.G992E | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.696); catalogued as COSV61984750; called by muse, varscan2
- SCYL2 | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as rs750714487, COSV62567954; called by muse, mutect2, varscan2
- SEL1L3 | c.2586-4del | Splice Region (DEL) | VAF 23/53 reads (43%) | catalogued as rs35927722; called by mutect2, varscan2
- SEMA6B | c.826del p.R276Afs*11 | Frame Shift Del (DEL) | VAF 81/216 reads (38%) | catalogued as rs781437207, COSV56702141, COSV56702780; called by mutect2, varscan2
- SEPHS2 | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.542); catalogued as COSV72100733; called by muse, mutect2
- SEPTIN3 | c.1012-4G>A | Splice Region (SNP) | VAF 16/48 reads (33%) | catalogued as COSV99352347; called by muse, mutect2, varscan2
- SERPINB10 | c.1097C>A p.P366Q | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.93); catalogued as COSV53073823; called by muse, mutect2, varscan2
- SERPINB2 | c.503dup p.I169Dfs*2 | Frame Shift Ins (INS) | VAF 30/130 reads (23%) | catalogued as rs754046467; called by pindel, varscan2
- SERPINE3 | c.1059G>T p.E353D | Missense Mutation (SNP) | VAF 68/218 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60878978; called by muse, mutect2, varscan2
- SFI1 | c.934C>T p.R312* | Nonsense Mutation (SNP) | VAF 28/90 reads (31%) | catalogued as rs1245906121; called by muse, mutect2, varscan2
- SGSM3 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 10/183 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV99960104, COSV99960636; called by muse, mutect2
- SHOX | c.101C>T p.T34M | Missense Mutation (SNP) | VAF 148/420 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); catalogued as rs751747648, COSV61861657; called by muse, mutect2, varscan2
- SHROOM1 | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as rs748264255, COSV60581765; called by muse, mutect2, varscan2
- SHROOM1 | c.1843C>T p.P615S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as COSV60581768; called by muse, mutect2, varscan2
- SIM1 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.937); catalogued as rs1371947558, COSV53497861; called by muse, mutect2, varscan2
- SKIDA1 | c.2485C>T p.R829C | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1459128060, COSV71610963; called by muse, mutect2, varscan2
- SLAMF1 | c.829del p.S277Afs*54 | Frame Shift Del (DEL) | VAF 36/104 reads (35%) | catalogued as rs751442558; called by mutect2, varscan2
- SLC12A5 | c.923+1G>A p.X308_splice (on ENST00000454036 / NM_001134771.2; = p.X285_splice on NM_020708.5) | Splice Site (SNP) | VAF 36/122 reads (30%) | catalogued as rs142641765, COSV99715688; called by muse, mutect2, varscan2
- SLC12A7 | c.2056del p.H686Tfs*11 | Frame Shift Del (DEL) | VAF 45/146 reads (31%) | catalogued as rs767964038; called by mutect2, pindel, varscan2
- SLC12A7 | c.1966G>A p.G656R | Missense Mutation (SNP) | VAF 107/280 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs777861615, COSV53762817; called by muse, mutect2, varscan2
- SLC13A3 | c.1519del p.L507Cfs*3 | Frame Shift Del (DEL) | VAF 37/152 reads (24%) | catalogued as rs1304724612; called by mutect2, pindel, varscan2
- SLC14A2 | c.1844C>T p.A615V | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs779206322, COSV54911486; called by muse, mutect2, varscan2
- SLC15A2 | c.829C>T p.R277* | Nonsense Mutation (SNP) | VAF 26/80 reads (33%) | catalogued as rs145317059; called by muse, mutect2, varscan2
- SLC22A14 | c.734C>T p.S245L | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs1078846, COSV99828319; called by muse, mutect2, varscan2
- SLC22A2 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 50/165 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); catalogued as rs371586429; called by muse, mutect2, varscan2
- SLC22A7 | c.52C>A p.L18M | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.094); catalogued as COSV65353311; called by muse, mutect2, varscan2
- SLC25A10 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs745715469; called by muse, mutect2, varscan2
- SLC25A20 | c.376G>T p.G126* | Nonsense Mutation (SNP) | VAF 21/144 reads (15%) | catalogued as COSV100033659, COSV59803460; called by muse, mutect2, varscan2
- SLC25A51 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 49/241 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.311); catalogued as rs551338195, COSV99643425; called by muse, mutect2, varscan2
- SLC27A1 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.262); catalogued as rs566825387; called by muse, mutect2, varscan2
- SLC28A2 | c.1200G>C p.G400= | Splice Region (SNP) | VAF 40/107 reads (37%) | catalogued as COSV61664430; called by muse, mutect2, varscan2
- SLC30A6 | c.546C>A p.S182R | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV99249662; called by muse, mutect2, varscan2
- SLC35E2B | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 63/230 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs1368230572; called by muse, mutect2, varscan2
- SLC35F5 | c.742del p.C248Afs*22 | Frame Shift Del (DEL) | VAF 11/27 reads (41%) | catalogued as rs577214214; called by mutect2, varscan2
- SLC38A4 | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.27); PolyPhen probably damaging (1); catalogued as rs1311032019, COSV56969984; called by muse, mutect2, varscan2
- SLC4A3 | c.1600G>A p.V534M | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs151023127, COSV56092613; called by muse, mutect2, varscan2
- SLC6A9 | c.919C>T p.R307* (on ENST00000360584 / NM_201649.4; = p.R253* on NM_006934.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 48/155 reads (31%) | catalogued as rs1246588755, COSV62210897; called by muse, mutect2, varscan2
- SLC7A7 | c.1213T>C p.W405R | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as rs752725969; called by muse, mutect2, varscan2
- SLCO1B3 | c.833dup p.P280Afs*6 | Frame Shift Ins (INS) | VAF 14/50 reads (28%) | catalogued as rs751405974; called by mutect2, varscan2
- SLCO2B1 | c.1238T>C p.I413T | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs762752722; called by mutect2, varscan2
- SLITRK2 | c.1481C>A p.T494K | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); catalogued as COSV59423617; called by muse, mutect2
- SMG1 | c.8395C>T p.R2799W | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1308928091, COSV67174448; called by muse, mutect2, varscan2
- SMPD2 | c.718G>A p.V240M | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.211); catalogued as rs142939267; called by muse, mutect2, varscan2
- SNPH | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs191018281, COSV60588819; called by muse, mutect2, varscan2
- SP140 | c.2015del p.K672Rfs*4 | Frame Shift Del (DEL) | VAF 27/94 reads (29%) | catalogued as rs746109620; called by mutect2, varscan2
- SPAG4 | c.1178del p.P393Qfs*7 | Frame Shift Del (DEL) | VAF 35/129 reads (27%) | catalogued as rs1292316291; called by mutect2, pindel, varscan2
- SPAG5 | c.2849C>T p.T950I | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as rs754060658; called by muse, mutect2, varscan2
- SPATA2L | c.1030T>C p.S344P | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as rs1191744700; called by muse, mutect2, varscan2
- SPPL2B | c.139C>T p.L47F | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as COSV101194687; called by muse, mutect2, varscan2
- SPTBN4 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 58/198 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58950819; called by muse, mutect2, varscan2
- SPTBN5 | c.8975G>A p.R2992Q | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as rs754604785; called by muse, mutect2, varscan2
- SPTBN5 | c.8378G>A p.R2793Q | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs770969080, COSV100311666; called by muse, mutect2, varscan2
- SRC | c.1489C>A p.L497I | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (1); PolyPhen probably damaging (0.993); catalogued as COSV62440702; called by muse, mutect2, varscan2
- SRCAP | c.5633del p.P1878Hfs*89 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | catalogued as rs748467821; called by mutect2, varscan2
- SRPRA | c.1060G>A p.V354M | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1323680588; called by muse, mutect2, varscan2
- SRSF6 | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs777495508, COSV54828086; called by muse, mutect2, varscan2
- SSPN | c.521G>T p.R174M | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54381437; called by muse, mutect2, varscan2
- ST3GAL1 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 40/116 reads (34%) | PolyPhen possibly damaging (0.851); catalogued as rs145826176; called by muse, mutect2, varscan2
- STAB2 | c.6991G>A p.V2331M | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs1168600619; called by muse, mutect2, varscan2
- STAG2 | c.1225G>T p.D409Y | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as rs773224655, COSV54358349, COSV99492729; called by muse, mutect2, varscan2
- STARD3 | c.99_101del p.S34del | In Frame Del (DEL) | VAF 16/37 reads (43%) | catalogued as rs774114973; called by pindel, varscan2
- STK24 | c.1100T>C p.I367T | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as rs539699022; called by muse, mutect2, varscan2
- SUN1 | c.1747G>A p.D583N (on ENST00000405266 / NM_001367651.1; = p.D463N on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.523); catalogued as rs755220201; called by muse, mutect2, varscan2
- SURF6 | c.358C>T p.R120* | Nonsense Mutation (SNP) | VAF 44/136 reads (32%) | catalogued as rs782430714, COSV63292717; called by muse, mutect2, varscan2
- SV2C | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753140281, COSV100455618; called by muse, mutect2, varscan2
- SVEP1 | c.5641G>A p.G1881S | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as COSV52836945; called by muse, mutect2, varscan2
- SYCP3 | c.643del p.I215Lfs*2 | Frame Shift Del (DEL) | VAF 22/68 reads (32%) | catalogued as rs761136347, CD035010; called by mutect2, varscan2
- SYNC | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs1054222836; called by muse, mutect2, varscan2
- SYNJ2 | c.1111del p.E371Rfs*14 | Frame Shift Del (DEL) | VAF 35/100 reads (35%) | catalogued as rs1258446424; called by mutect2, pindel, varscan2
- SYNPO2L | c.2462del p.F821Sfs*27 (on ENST00000394810 / NM_001114133.3; = p.F597Sfs*27 on NM_024875.5) | Frame Shift Del (DEL) | VAF 7/42 reads (17%) | catalogued as COSV65736761; called by mutect2, pindel, varscan2
- SYT1 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1431810122, COSV54046323, COSV54055678; called by muse, mutect2, varscan2
- TAB1 | c.493G>T p.G165W | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV53371974; called by muse, mutect2, varscan2
- TADA2A | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as rs1036733761; called by muse, mutect2, varscan2
- TAF13 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.022); catalogued as rs374542323; called by muse, mutect2, varscan2
- TAF7L | c.719dup p.V241Gfs*3 | Frame Shift Ins (INS) | VAF 29/68 reads (43%) | catalogued as COSV61258097; called by mutect2, varscan2
- TAS2R42 | c.745del p.S249Pfs*18 | Frame Shift Del (DEL) | VAF 22/80 reads (28%) | catalogued as rs753101364; called by mutect2, varscan2
- TBC1D16 | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs267605078; called by muse, mutect2, varscan2
- TBC1D25 | c.1972C>T p.R658C | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs1556986194, COSV100952260; called by muse, mutect2, varscan2
- TBC1D9B | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as rs1371101669; called by muse, mutect2, varscan2
- TBX22 | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV64785128; called by muse, mutect2
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 38/104 reads (37%) | catalogued as rs758822980; called by mutect2, varscan2
- TCF20 | c.5826del p.L1943Cfs*118 | Frame Shift Del (DEL) | VAF 11/36 reads (31%) | catalogued as rs756457255; called by mutect2, pindel, varscan2
- TEAD1 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.217); catalogued as COSV57566512; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 24/80 reads (30%) | catalogued as rs763321097; called by mutect2, varscan2
- TENM3 | c.1997C>T p.T666M | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.19); catalogued as rs374213747; called by muse, mutect2, varscan2
- TENM3 | c.6847G>T p.A2283S | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as COSV69316758; called by muse, mutect2, varscan2
- TENT5D | c.1049A>G p.Q350R | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as rs765671795; called by muse, mutect2, varscan2
- TET3 | c.1135del p.Q379Rfs*162 | Frame Shift Del (DEL) | VAF 15/61 reads (25%) | catalogued as COSV59880837; called by mutect2, pindel, varscan2
- TEX15 | c.5122dup p.R1708Kfs*6 (on ENST00000256246; = p.R2091Kfs*6 on NM_001350162.2) | Frame Shift Ins (INS) | VAF 14/38 reads (37%) | catalogued as rs778104055; called by mutect2, varscan2
- TFCP2 | c.275-1G>A p.X92_splice | Splice Site (SNP) | VAF 11/28 reads (39%) | catalogued as COSV99227822; called by muse, mutect2, varscan2
- TGFB2 | c.194C>A p.P65Q | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV65110036; called by muse, mutect2, varscan2
- TIA1 | c.562G>A p.A188T (on ENST00000433529 / NM_001351511.1; = p.A177T on NM_022037.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs756853891; called by muse, mutect2, varscan2
- TIGD4 | c.283T>C p.Y95H | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV100428106; called by muse, varscan2
- TLX2 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.349); catalogued as rs773898981; called by muse, mutect2, varscan2
- TM9SF3 | c.214del p.S72Vfs*31 | Frame Shift Del (DEL) | VAF 24/69 reads (35%) | catalogued as rs760930120; called by mutect2, varscan2
- TMCO6 | c.257C>A p.A86D | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as COSV99347367; called by muse, mutect2
- TMEM120A | c.725G>A p.S242N | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.957); catalogued as COSV100115734; called by muse, mutect2, varscan2
- TMEM126A | c.218G>T p.G73V | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58735536; called by muse, mutect2, varscan2
- TMEM59L | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 48/138 reads (35%) | catalogued as rs763304571, COSV53242657; called by muse, mutect2, varscan2
- TMEM8B | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.532); catalogued as rs748426089, COSV65077052; called by muse, mutect2
- TNIP1 | c.1796G>A p.R599H | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.534); catalogued as rs768467028; called by muse, mutect2, varscan2
- TNKS2 | c.1865del p.N622Tfs*29 | Frame Shift Del (DEL) | VAF 24/64 reads (38%) | catalogued as rs749004712; ClinVar: not provided; called by mutect2, varscan2
- TNRC6B | c.5482G>T p.G1828* (on ENST00000454349 / NM_001162501.2; = p.G1718* on NM_015088.3) | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as COSV57299567; called by muse, mutect2, varscan2
- TNRC6C | c.1969del p.E657Rfs*3 | Frame Shift Del (DEL) | VAF 39/159 reads (25%) | catalogued as COSV56953297; called by mutect2, pindel, varscan2
- TOP1MT | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1470596588, COSV100239306; called by muse, mutect2, varscan2
- TOPORS | c.380G>A p.C127Y | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62117324; called by muse, varscan2
- TOX3 | c.317T>C p.F106S | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV54871594; called by muse, mutect2, varscan2
- TP53 | c.902dup p.G302Rfs*4 | Frame Shift Ins (INS) | VAF 12/101 reads (12%) | catalogued as COSV53177081; called by mutect2, pindel, varscan2
- TPR | c.6221C>T p.P2074L | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs758791554, COSV66602345; called by muse, mutect2, varscan2
- TRAFD1 | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV57504953; called by muse, mutect2, varscan2
- TRAIP | c.1307G>A p.R436H | Missense Mutation (SNP) | VAF 76/222 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.048); catalogued as rs148292576; called by muse, mutect2, varscan2
- TRAK2 | c.1070C>T p.T357I | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100217099; called by muse, mutect2
- TRIM24 | c.2675del p.K892Rfs*9 (on ENST00000343526 / NM_015905.3; = p.K858Rfs*9 on NM_003852.4) | Frame Shift Del (DEL) | VAF 17/55 reads (31%) | catalogued as rs1563068799; called by pindel, varscan2
- TRIM25 | c.646del p.A216Rfs*8 | Frame Shift Del (DEL) | VAF 7/64 reads (11%) | catalogued as rs746988951; called by mutect2, pindel, varscan2
- TRIM42 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs763391261, COSV53881671; called by muse, mutect2, varscan2
- TRIM45 | c.1426G>A p.V476I | Missense Mutation (SNP) | VAF 68/209 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs533016681, COSV56712893; called by muse, mutect2, varscan2
- TRIM77 | c.591C>G p.H197Q | Missense Mutation (SNP) | VAF 61/166 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as COSV68066659; called by muse, mutect2, varscan2
- TRIO | c.3158C>T p.T1053M | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.72); catalogued as rs754511053, COSV100710522; called by muse, mutect2, varscan2
- TRPC6 | c.1128del p.K376Nfs*3 | Frame Shift Del (DEL) | VAF 8/47 reads (17%) | catalogued as COSV60250864; called by mutect2, pindel, varscan2
- TRPC7 | c.364G>A p.V122M | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1338221982, COSV61458314; called by muse, mutect2, varscan2
- TSHZ3 | c.2247G>A p.M749I | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as COSV53663704; called by muse, mutect2, varscan2
- TTC28 | c.6551G>A p.G2184D | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.05); catalogued as COSV104431547; called by muse, mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 36/94 reads (38%) | catalogued as rs763254614; called by mutect2, varscan2
- TTLL4 | c.3023G>A p.R1008Q | Missense Mutation (SNP) | VAF 76/203 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); catalogued as rs377347204; called by muse, mutect2, varscan2
- TTN | c.85258G>A p.V28420I (on ENST00000591111; = p.V20996I on NM_003319.4) | Missense Mutation (SNP) | VAF 73/181 reads (40%) | PolyPhen benign (0); catalogued as rs138958733; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUB | c.1415G>A p.R472Q (on ENST00000299506 / NM_177972.3; = p.R527Q on NM_003320.4) | Missense Mutation (SNP) | VAF 72/181 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200534110; called by muse, mutect2, varscan2
- TUBGCP3 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 6/108 reads (6%) | catalogued as COSV99997193; called by muse, mutect2
- TYK2 | c.1825C>T p.R609* | Nonsense Mutation (SNP) | VAF 28/87 reads (32%) | catalogued as rs749285570; called by muse, mutect2, varscan2
- TYW3 | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs369783452; called by muse, mutect2, varscan2
- U2AF2 | c.531dup p.L178Afs*15 | Frame Shift Ins (INS) | VAF 23/61 reads (38%) | catalogued as rs758316280; called by mutect2, varscan2
- UAP1L1 | c.683del p.G228Afs*125 | Frame Shift Del (DEL) | VAF 19/92 reads (21%) | catalogued as COSV100814543; called by mutect2, pindel, varscan2
1,180 further variants in this file (652 protein-altering or splice-affecting, 375 silent, 153 other) are not listed here.
